Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MG, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MG-06A (Metastatic).

PathNet History Upload External
Client

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL

Melanoma. Axillary contents. Apical node beyond long stitch.

SPECIMEN INFORMATION

(R) axillary dissection.

MACROSCOPIC DESCRIPTION

"Apical node beyond long stitch axillary contents". A piece of fatty tissue with muscle measuring 150 x 110 x 50mm. A suture is present at one end indicating the apex margin. Multiple lymph nodes are dissected from this axillary section.

- A. 4 apical nodes.
- B. 1 large metastatic node 35mm across.
- C. 1 node 16mm across.
- D. 4 nodes.
- E. 1 node.
- F. 4 nodes.
- G. 3 nodes.

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary
C77.3
lw 8/24/11

MICROSCOPIC REPORT

"Apical node beyond long stitch axillary contents".

B. Metastatic epithelioid cell malignant melanoma replaces most of the lymph node. No extranodal spread seen.

A,C-G. The remaining 17 lymph nodes show no evidence of malignancy.

Electronic signature

SUMMARY / KEY WORDS

Axillary lymph node - malignant melanoma, metastatic
Haematopathology resection

lw 8/24/11

Source: NCI Genomic Data Commons file 6c2980ff-24a8-4876-a954-92d376012ae0 (TCGA-EE-A2MG.11CFC905-FDAC-49D4-B159-F4E93803E460.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).